Surgical pathology report (de-identified scan), TCGA case TCGA-Q1-A73O, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Oklahoma HSC, specimen TCGA-Q1-A73O-01A (Primary Tumor).

[page 1 of 2]
RUN DATE:
RUN TIME:
BY:

PAGE:1

SPEC #:
STATUS:

Obtained:
Received:

Subm Dr:

CLINICAL HISTORY:
CERVICAL MASS, ANEMIA

SPECIMEN/PROCEDURE:

1. CERVIX
2. CERVIX - TUMOR

ICD-O-3
Carcinoma, squamous cell,
large cell, non-keratinizing NOS
807213
Site Cervix NOS C53.9
Qx 8/15/13

IMPRESSION:

- 1) CERVIX, BIOPSY:
Invasive squamous cell carcinoma, large cell non-keratinizing type, poorly differentiated.
- 2) CERVIX, BIOPSY:
Invasive squamous cell carcinoma, large cell non-keratinizing type, poorly differentiated.

Dictated by:
Entered:

SPECIAL STAINS/PROCEDURES:

One initial frozen section (1F).

Dictated by:

GROSS DESCRIPTION:

- 1) Received fresh for frozen section examination, labeled with the patient's name, medical record number and "cervical mass," is a 1.2 x 0.8 x 0.5 cm portion of red tan tissue. The specimen is entirely submitted for frozen section evaluation. The frozen section residue is submitted in cassette 1F.

FROZEN SECTION DIAGNOSIS: Squamous cell carcinoma. Reported to
on

- 2) Received fresh labeled with the patient's name, medical record number and "cervix, tumor, permanent," is a 1.5 x 0.5 x 0.5 cm portion of friable white tan tissue. The specimen trisected and entirely submitted in cassettes 2A-2B.

Dictated by:
Entered:

** CONTINUED ON NEXT PAGE **

[page 2 of 2]
COPIES TO:

CPT Codes:

FS INITIAL/88331, H&E-88313, CERVICAL BIOPSY/88305/2

ICD9 Codes:

180.9

Resident Physician:

I have personally reviewed the material
(specimen/slide) and approve this final report.

Electronically Signed by:

** END OF REPORT **

Criteria	lu 7/24/13	No
HPV Discrepancy		✓
Diff/Syncronous Primary Noted		✓

Source: NCI Genomic Data Commons file 67c46357-507c-4dc3-8dcd-fca97bcc8968 (TCGA-Q1-A73O.2D4BBE0A-11E4-46C1-8416-FA0E724B53FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).